Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4IV, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4IV-01A (Primary Tumor).

Gross Description: In prepylorus, there is an ulcer with 3x2x1cm in size, firm and myxoid gray surface.

Microscopic Description: Mucosa is ulcerated and necrotic. The tumor is composed of groups of signet-ring cell has a large mucin vacuole that fills the cytoplasm and displaces the nucleus. Tumor intervenes in muscle bundles and is invasion in serosa. Nuclei are hyperchromatic and irregular enlarged with prominent nucleoli. Mitoses are present. Stroma is predominantly invasion of lymphocytes.

Diagnosis Details: Adenocarcinoma, diffuse type, infiltrating serosa.

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Antrum

ICD-O-3

Tumor size: 3 x 2 x 1 cm

adenocarcinoma, diffuse type 8145/3

Site: stomach, antrum C16.3

Tumor features: Ulcerated

Histologic type: Adenocarcinoma, diffuse type

hw
10/8/12

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 3/9 positive for metastasis (Regional 3/9)

Lymphatic invasion: Present

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

hw
10/24/12

Source: NCI Genomic Data Commons file bfb1b008-7363-4945-b552-f584fff49f83 (TCGA-BR-A4IV.F4214EF2-C310-4BEA-A90A-3FA593B250BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).